Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JF, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JF-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 3/11/11

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Intraoperative examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Lesion excision – Lesion in the left breast – outer upper quad.

Unit in charge

Physician in charge:

Material collected on

Material received on

Expected time of examination: 20 minutes (from receipt of material)

Clinical diagnosis: Cancer of the left breast.

Examination performed on:

Result of intraoperative examination:

Carcinoma invasivum

Compliance validated by:

Examination performed on:

Macroscopic description:

Fragment of the breast sized 6 x 5 x 2 cm.

Tumour sized 1.2 x 0.8 x 0.7 cm in the middle.

Minimum margin: 1 cm.

Histopathological diagnosis:

Carcinoma ductale invasivum NHG3 (3 + 3 + 2/10 mitoses/10 HPF - visual area 0.55 mm). pT1c

Invasive ductal carcinoma of the left breast.

Compliance validated by

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors found in neoplastic cell nuclei.

No progesterone receptors found in neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Diagnostic Discrepancy		X
Dual/Sing. Response Primary Nod.		X

Source: NCI Genomic Data Commons file 9ba05841-185f-4e8b-b410-1e30fd16d81e (TCGA-D8-A1JF.03724E51-8430-414F-B483-2CB92D6A878F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).